Gene-level copy-number profile of tumor specimen TCGA-BB-7864-01A from TCGA case TCGA-BB-7864, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 61.1 years (22,317 days).
Specimen TCGA-BB-7864-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.df8b5092-db1b-4d1f-bc0c-ecae146d5c6f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BB-7864-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 830 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/db866d93-93ed-4b54-8b96-7f61cb366973

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 33; copy number 1: 6,663; copy number 2: 45,980; copy number 3: 4,652; copy number 4: 1,786; copy number 5: 677; copy number 6: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-BB-7864-01): tumor purity 0.65, ploidy 2.11, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): 29 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,134,358–48,711,226, 15 genes: POLR2KP2, ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2.
- chr13:79,090,783–80,134,368, 14 genes: NIPA2P5, BCAS2P3, RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, AL136442.1, LINC01038, LINC00382, AL158064.1, LINC01080, AL137781.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 679 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:178,960,121–182,655,880, 76 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr8:103,500,696–104,256,094, 1 gene, copy number 5 (within-gene range 3–5): RIMS2.
- chr8:103,768,281–145,066,685, 600 genes, copy number 5 (broad region; genes not listed).
- chr12:90,576,402–90,889,917, 1 gene, copy number 6 (within-gene range 2–6): LINC02822.
- chr12:90,809,207–90,810,689, 1 gene, copy number 6: AC112481.1.

Autosomal genes at a single copy (total copy number 1): 4,281. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
